Somatic mutation profile of tumor specimen TCGA-CV-6935-01A (aliquot TCGA-CV-6935-01A-11D-1912-08) from TCGA case TCGA-CV-6935, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 67.9 years (24,799 days).
Specimen TCGA-CV-6935-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e0eed7-bd86-48e2-9941-477c941703b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6935-10A (Blood Derived Normal), aliquot TCGA-CV-6935-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e71c35a4-6201-418a-9337-cbd776531505

The open-access MAF lists 240 somatic variants for this specimen: 185 protein-altering or splice-affecting, 48 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 48, Nonsense Mutation 10, Splice Site 4, In Frame Del 4, Intron 3, Frame Shift Ins 2, Frame Shift Del 2, Translation Start Site 1, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960212, COSV67961561; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 25/100 reads (25%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 73/98 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519982, CM107067, COSV52660956, COSV52677021, COSV52760397, COSV52839973; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.2214G>C p.E738D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100429799, COSV58050840; called by muse, mutect2
- ACY3 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV99663155; called by muse, mutect2, varscan2
- AFF2 | c.3843G>T p.M1281I | Missense Mutation (SNP) | VAF 67/85 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54011412, COSV99666256; called by muse, mutect2, varscan2
- AGL | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99650038; called by muse, mutect2, varscan2
- AKAP13 | c.3400G>A p.V1134M | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.339); catalogued as COSV100774697; called by muse, mutect2, varscan2
- ALG5 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as rs201593403, COSV99523831; called by muse, mutect2, varscan2
- ANO5 | c.2559G>T p.M853I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.422); catalogued as COSV100202224, COSV61089680; called by muse, mutect2, varscan2
- APC | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs149154604, COSV57322722, COSV99969383; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- APOB | c.10922C>A p.S3641Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99265512, COSV99268083; called by muse, mutect2, varscan2
- ARFGEF3 | c.2377G>A p.V793M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416949045, COSV99294708; called by muse, mutect2, varscan2
- ARHGAP15 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99713592; called by muse, mutect2, varscan2
- ARHGAP17 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV99254056; called by muse, mutect2, varscan2
- ARHGAP30 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100920504; called by muse, mutect2, varscan2
- BAAT | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV99408679; called by muse, mutect2, varscan2
- BIRC6 | c.9472G>A p.E3158K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101428896; called by muse, mutect2, varscan2
- BNC1 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.057); catalogued as rs961473043, COSV100597484; called by muse, mutect2, varscan2
- CACNA1E | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100705348; called by muse, varscan2
- CAPN6 | c.1435A>C p.T479P | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV100137094; called by muse, mutect2, varscan2
- CCDC150 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV99777386; called by muse, mutect2
- CCDC181 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1260628707, COSV100890397; called by muse, mutect2, varscan2
- CDH9 | c.1802C>A p.T601N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50324022, COSV50529283; called by muse, mutect2, varscan2
- CDK8 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67423041; called by muse, mutect2, varscan2
- CEP72 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs143077618; called by muse, mutect2, varscan2
- CFAP43 | c.4434T>C p.T1478= | Splice Region (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100829476; called by muse, mutect2, varscan2
- CMTM1 | c.82-2A>T p.X28_splice (on ENST00000457188 / NM_181269.3; = p.X145_splice on NM_052999.4) | Splice Site (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99862696; called by muse, mutect2, varscan2
- CNKSR2 | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99669765; called by muse, mutect2, varscan2
- COL4A1 | c.3031G>A p.G1011R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011195, COSV101011605; called by muse, mutect2, varscan2
- COL6A2 | c.2994C>A p.H998Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99385456; called by muse, mutect2, varscan2
- COX10 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99887088; called by muse, mutect2, varscan2
- CSMD3 | c.10672C>A p.L3558I (on ENST00000297405 / NM_001363185.1; = p.L3389I on NM_052900.3) | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV52131699, COSV52175526, COSV99847705; called by muse, mutect2, varscan2
- CSMD3 | c.2187G>T p.M729I (on ENST00000297405 / NM_001363185.1; = p.M625I on NM_052900.3) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV52157784, COSV99847709; called by muse, mutect2, varscan2
- CYP4F22 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.329); catalogued as rs773826320, COSV99513175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAB2 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV100298359; called by muse, mutect2, varscan2
- DCHS1 | c.8972G>A p.R2991Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs200152314, COSV54999477; called by muse, mutect2, varscan2
- DDI2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs750222182, COSV100197895; called by muse, mutect2, varscan2
- DENND2B | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs144868309; called by muse, mutect2, varscan2
- DMD | c.5996C>T p.T1999I | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100822816; called by muse, mutect2, varscan2
- DMD | c.4604C>A p.T1535K | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV100822817, COSV63771742; called by muse, mutect2, varscan2
- DNAH5 | c.12306C>A p.C4102* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99454211; called by muse, mutect2, varscan2
- DOCK9 | c.5900C>T p.S1967L (on ENST00000376460 / NM_001366676.2; = p.S1968L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs368761374; called by muse, mutect2, varscan2
- DRP2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 59/76 reads (78%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100872069; called by muse, mutect2, varscan2
- DUS3L | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100288484; called by muse, mutect2, varscan2
- DUSP6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs1245148584, COSV99684149; called by muse, mutect2, varscan2
- DYRK1B | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV99695430; called by muse, mutect2, varscan2
- ENTR1 | c.653C>T p.P218L (on ENST00000357365 / NM_001039707.2; = p.P195L on NM_006643.4) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as rs1052773037, COSV53743030; called by muse, mutect2, varscan2
- ERICH3 | c.4294G>T p.G1432C | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100445801; called by muse, mutect2, varscan2
- ERV3-1 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as COSV99276093; called by muse, mutect2, varscan2
- FAM135B | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV52718249; called by muse, mutect2, varscan2
- FBXL7 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100310865; called by muse, mutect2, varscan2
- FCAR | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as rs773603335, COSV100629206, COSV62028187; called by muse, mutect2, varscan2
- FCSK | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV55368383; called by muse, mutect2, varscan2
- FLG | c.7195T>C p.S2399P | Missense Mutation (SNP) | VAF 39/566 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1219299454, COSV100912209; called by muse, mutect2
- FMN2 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs749555339, COSV100143607, COSV100147115; called by muse, mutect2, varscan2
- GALNT17 | c.1500G>T p.Q500H | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356239; called by muse, mutect2, varscan2
- GALNTL5 | c.663T>A p.D221E | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0.114); catalogued as rs759086684, COSV101217965; called by muse, mutect2, varscan2
- GIN1 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV101204421; called by muse, mutect2, varscan2
- GPR89B | c.349T>C p.W117R | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100032635; called by mutect2, varscan2
- GRIA4 | c.1363G>C p.A455P | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99234525; called by muse, mutect2, varscan2
- GRIN2A | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV100411074, COSV58057828; called by muse, mutect2, varscan2
- GRM8 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV100286124; called by muse, mutect2, varscan2
- H3C10 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV60797759; called by muse, mutect2
- HAO1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV101113328; called by muse, mutect2, varscan2
- HCRTR2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904405; called by muse, mutect2, varscan2
- HMCN1 | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 53/120 reads (44%) | catalogued as COSV99635804; called by muse, mutect2, varscan2
- HRH4 | c.365A>T p.Y122F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99908032; called by muse, mutect2, varscan2
- HTR2A | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs192924120, COSV101096863, COSV66326853; called by muse, mutect2, varscan2
- IARS1 | c.2781C>A p.F927L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100986736; called by muse, mutect2, varscan2
- INHBA | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 199/478 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as rs779271157, COSV54223438; called by muse, mutect2, varscan2
- IRF8 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV99236860; called by muse, mutect2, varscan2
- IVNS1ABP | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as COSV100832576; called by muse, mutect2, varscan2
- KANSL1L | c.2308T>G p.Y770D | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99911016; called by muse, mutect2, varscan2
- KCNJ3 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV99716503; called by muse, mutect2, varscan2
- KCNN2 | c.1676G>T p.R559L (on ENST00000264773; = p.R771L on NM_021614.4) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.072); catalogued as COSV99300464; called by muse, mutect2, varscan2
- KDM6A | c.2939-1G>C p.X980_splice | Splice Site (SNP) | VAF 11/12 reads (92%) | catalogued as COSV100938585, COSV65042892; called by muse, mutect2, varscan2
- KIAA1217 | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100907946, COSV100908383; called by muse, mutect2, varscan2
- KIDINS220 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99876473; called by muse, mutect2, varscan2
- KIF26B | c.3335G>T p.G1112V | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as COSV100833419; called by muse, mutect2, varscan2
- KRI1 | c.1774C>G p.R592G | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs200311568, COSV100469849; called by muse, varscan2
- KRTAP11-1 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV100190829; called by muse, mutect2, varscan2
- KRTAP27-1 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239785; called by muse, varscan2
- LAMA1 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101056349, COSV101057731; called by muse, mutect2, varscan2
- LEPR | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100756750; called by muse, mutect2, varscan2
- LRP4 | c.2254A>G p.I752V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV101066888; called by muse, mutect2, varscan2
- LRRK1 | c.2593G>T p.D865Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99443185, COSV99444079; called by muse, mutect2, varscan2
- MET | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.8); catalogued as COSV100577389; called by muse, mutect2, varscan2
- METTL3 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV52972141; called by muse, mutect2, varscan2
- MGAM | c.3568A>C p.S1190R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101527751; called by muse, mutect2, varscan2
- MINDY3 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99511003; called by muse, mutect2, varscan2
- MITD1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99175568, COSV99175587; called by muse, mutect2, varscan2
- MMP13 | c.1120G>C p.G374R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99506869; called by muse, mutect2, varscan2
- MORC1 | c.977A>C p.Q326P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV99227779; called by muse, mutect2
- MTMR11 | c.895G>A p.D299N (on ENST00000439741 / NM_001145862.2; = p.D227N on NM_181873.3) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV100809309; called by muse, mutect2, varscan2
- MUC16 | c.40488G>T p.M13496I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.593); catalogued as rs769281480, COSV101110090; called by muse, mutect2, varscan2
- MUC5B | c.5678C>A p.S1893Y | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV101500764; called by muse, mutect2, varscan2
- MYLK3 | c.1135G>T p.G379W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101189216; called by muse, mutect2, varscan2
- MYO18B | c.3488C>A p.T1163N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100125181; called by muse, mutect2, varscan2
- NPAP1 | c.2912C>G p.A971G | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV100276197; called by muse, mutect2, varscan2
- NPY5R | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100642934, COSV58452759; called by muse, mutect2, varscan2
- NSMF | c.1202G>C p.G401A (on ENST00000371475 / NM_001130969.3; = p.G399A on NM_015537.4) | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99688991, COSV99689529; called by muse, mutect2, varscan2
- NUDT9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV100139369; called by muse, mutect2, varscan2
- NUP210L | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99669127; called by muse, mutect2, varscan2
- OGDHL | c.2524A>T p.I842F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV100934527; called by muse, mutect2, varscan2
- OR2AT4 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100532411; called by muse, mutect2, varscan2
- OR2T3 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 210/388 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100613414; called by muse, varscan2
- OR2T3 | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 116/423 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100613006, COSV100613416; called by muse, varscan2
- OR4A47 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV101487111; called by muse, mutect2, varscan2
- OR4C46 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.286); catalogued as rs1446043123, COSV100060887, COSV100060997; called by muse, mutect2, varscan2
- OR4Q3 | c.617T>A p.V206E | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100057395; called by muse, mutect2, varscan2
- OR4X2 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100183348; called by muse, mutect2, varscan2
- OR52L1 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV100176354; called by muse, mutect2, varscan2
- OR5H1 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763302013, COSV100641775; called by muse, mutect2, varscan2
- OR5M1 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV101591610; called by muse, mutect2, varscan2
- OR5T3 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100282682, COSV100282934; called by muse, mutect2, varscan2
- OR6K2 | c.846G>C p.L282F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV62744195; called by muse, mutect2, varscan2
- P2RY2 | c.1107C>G p.S369R | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs145119561, COSV100232858; called by muse, mutect2, varscan2
- PABPC4 | c.1093G>T p.V365F | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100790931; called by muse, mutect2, varscan2
- PBX2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1210876222, COSV66709402; called by muse, mutect2, varscan2
- PCDH10 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99994532; called by muse, mutect2, varscan2
- PCDHB15 | c.2267C>A p.T756K | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.211); catalogued as COSV50961667, COSV99179227; called by muse, mutect2, varscan2
- PCDHGA2 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV99530476, COSV99546985; called by muse, varscan2
- PCDHGB3 | c.1120C>A p.L374I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs781132718, COSV99546987; called by muse, mutect2, varscan2
- PCLO | c.8095C>A p.P2699T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100437801, COSV61624916; called by muse, mutect2, varscan2
- PDE10A | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV100605796; called by muse, mutect2, varscan2
- PDZRN3 | c.2808G>T p.R936S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99732073; called by muse, mutect2, varscan2
- PEAK1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV100433444, COSV56933425; called by muse, mutect2
- PGM5 | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.071); catalogued as COSV101124058, COSV67167687; called by muse, mutect2, varscan2
- PKD2L1 | c.2082G>T p.E694D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100559454; called by muse, mutect2, varscan2
- PKHD1L1 | c.3925G>A p.E1309K | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV101006833; called by muse, mutect2, varscan2
- PKHD1L1 | c.7741C>A p.H2581N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101006834; called by muse, mutect2, varscan2
- PLCH1 | c.2998G>A p.A1000T (on ENST00000340059 / NM_001130960.2; = p.A992T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV58186255, COSV58200092; called by muse, mutect2, varscan2
- PLEKHG3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55983599; called by muse, mutect2, varscan2
- PLXNA1 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs753152143, COSV99304110; called by muse, mutect2, varscan2
- PMFBP1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV99401523; called by muse, mutect2, varscan2
- PPP1R9A | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750720867, COSV99198705; called by muse, varscan2
- PRRC2C | c.3013G>T p.E1005* (on ENST00000367742; = p.E1003* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100146065; called by muse, mutect2, varscan2
- PRRX1 | c.242-1G>C p.X81_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | catalogued as rs540157709, COSV99510331; called by muse, mutect2, varscan2
- PRSS37 | c.568-1G>T p.X190_splice | Splice Site (SNP) | VAF 12/17 reads (71%) | catalogued as COSV100633921; called by muse, mutect2
- PSKH2 | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.288); catalogued as COSV52612324, COSV99405399; called by muse, mutect2, varscan2
- PUDP | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV101128300; called by muse, mutect2, varscan2
- RECQL5 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100512360; called by muse, mutect2, varscan2
- RELT | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99293105; called by muse, mutect2, varscan2
- RFX5 | c.1487C>G p.S496* | Nonsense Mutation (SNP) | VAF 85/284 reads (30%) | catalogued as rs1459006688, COSV99303322; called by muse, mutect2, varscan2
- RGS7 | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100470945; called by muse, mutect2, varscan2
- ROS1 | c.3365G>T p.C1122F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV63857079; called by muse, mutect2, varscan2
- ROS1 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100877705; called by muse, mutect2, varscan2
- RPS6KB1 | c.1569G>C p.M523I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as rs1463062966, COSV99847754; called by muse, mutect2, varscan2
- RYR2 | c.2185G>C p.G729R | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772899; called by muse, mutect2, varscan2
- RYR2 | c.9409T>A p.L3137I | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as COSV100772901; called by muse, mutect2, varscan2
- RYR3 | c.5132G>C p.R1711P | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101214594, COSV66801666; called by muse, mutect2, varscan2
- SEZ6L2 | c.1745T>A p.L582Q (on ENST00000308713 / NM_001114099.3; = p.L512Q on NM_012410.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100435860; called by muse, mutect2, varscan2
- SLC2A2 | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100049505; called by muse, mutect2, varscan2
- SPACA1 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.203); catalogued as COSV99389783; called by muse, mutect2, varscan2
- SPANXN2 | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 287/371 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV100980004; called by muse, varscan2
- STK10 | c.2199G>T p.Q733H | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV99452319; called by muse, mutect2, varscan2
- TCEANC2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770131308, COSV52369805; called by muse, mutect2, varscan2
- THEMIS | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100965582; called by muse, mutect2, varscan2
- THRA | c.1166C>A p.P389Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV99225794; called by muse, mutect2, varscan2
- TNR | c.1310_1311insT p.F438Lfs*18 | Frame Shift Ins (INS) | VAF 140/333 reads (42%) | catalogued as COSV99691565; called by mutect2, pindel, varscan2
- TNS1 | c.586A>T p.N196Y | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99411903; called by muse, mutect2, varscan2
- TRIM39 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.338); catalogued as COSV100935918, COSV64955688; called by muse, mutect2, varscan2
- TRRAP | c.9083A>G p.N3028S (on ENST00000359863 / NM_001244580.1; = p.N2999S on NM_003496.3) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as COSV100722974; called by muse, mutect2, varscan2
- TTN | c.50987G>T p.R16996L (on ENST00000591111; = p.R9572L on NM_003319.4) | Missense Mutation (SNP) | VAF 143/253 reads (57%) | PolyPhen probably damaging (0.998); catalogued as COSV100613682, COSV100630189; called by muse, mutect2, varscan2
- TTN | c.16058G>C p.W5353S (on ENST00000591111; = p.W4426S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/185 reads (21%) | PolyPhen possibly damaging (0.714); catalogued as rs794729613, COSV100630192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13A | c.4505C>T p.T1502M | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761475197, COSV99409567; called by muse, mutect2, varscan2
- VPS50 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52496465, COSV52496660, COSV99298510; called by muse, mutect2, varscan2
- WNT8B | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100649133; called by muse, mutect2, varscan2
- ZDBF2 | c.792G>C p.M264I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100985551; called by muse, mutect2, varscan2
- ZNF112 | c.1634G>C p.R545T (on ENST00000337401 / NM_001083335.2; = p.R539T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100496290; called by muse, mutect2, varscan2
- ZNF226 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100335258; called by muse, mutect2, varscan2
- ZNF521 | c.3145G>T p.G1049W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV100833407; called by muse, mutect2, varscan2
- ZNF804B | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as rs1376240236, COSV100301684; called by muse, mutect2, varscan2
- ZNF878 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV101521260; called by muse, mutect2, varscan2
- CRB1 | c.1384_1398del p.D462_G466del | In Frame Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1731G>C p.K577N | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- FGF23 | c.523_524delinsT p.R175Cfs*16 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by pindel, varscan2*
- FSIP2 | c.16195dup p.S5399Ffs*16 | Frame Shift Ins (INS) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPRIPL2 | c.1247_1249del p.L416del | In Frame Del (DEL) | VAF 76/200 reads (38%) | called by pindel, varscan2
- PTPRN | c.1221del p.M408Cfs*33 | Frame Shift Del (DEL) | VAF 50/89 reads (56%) | called by mutect2, pindel, varscan2
- SETX | c.3609_3632del p.R1203_R1211delinsS | In Frame Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.39C>G p.S13R | Missense Mutation (SNP) | VAF 75/473 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); called by muse, varscan2
- SSU72P8 | c.124G>C p.V42L | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ABT1 | c.162G>T p.P54= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99223344; called by muse, mutect2, varscan2
- ALG13 | c.48C>T p.L16= | Silent (SNP) | VAF 142/175 reads (81%) | catalogued as COSV99323027; called by muse, mutect2, varscan2
- AOX1 | c.603C>G p.L201= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV101022236, COSV65979983; called by muse, mutect2, varscan2
- APOBEC2 | c.259C>A p.R87= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV99775441; called by muse, mutect2, varscan2
- CD226 | c.165C>T p.T55= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs1303772197, COSV99711521; called by muse, mutect2, varscan2
- CDH17 | c.1293C>A p.T431= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99218023; called by mutect2, varscan2
- COL19A1 | c.1812A>T p.P604= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100507529; called by muse, mutect2, varscan2
- CYP11B2 | c.978G>T p.T326= | Silent (SNP) | VAF 31/196 reads (16%) | catalogued as COSV100011392; called by muse, mutect2, varscan2
- DENND4C | c.1536G>T p.P512= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as COSV100991561, COSV66823265; called by muse, mutect2, varscan2
- DOCK3 | c.5205G>A p.S1735= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as rs369636952; called by muse, mutect2, varscan2
- ENPP3 | c.2391C>T p.C797= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs777387463, COSV100718088; called by muse, mutect2, varscan2
- FAM135B | c.3879C>G p.L1293= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV99427606; called by muse, mutect2
- FBN1 | c.924C>T p.V308= | Silent (SNP) | VAF 56/67 reads (84%) | catalogued as rs745503374, COSV100356412; called by muse, mutect2, varscan2
- FREM2 | c.8061G>T p.G2687= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV99750899; called by muse, mutect2, varscan2
- GLUD1 | c.501G>A p.L167= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99518418; called by muse, mutect2, varscan2
- HECTD4 | c.10536C>T p.A3512= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as rs780401363, COSV101108376; called by mutect2, varscan2
- HNF1A | c.1854C>A p.I618= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as CM993818, COSV99983009; called by mutect2, varscan2
- HSF2BP | c.114A>T p.I38= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV99375764; called by muse, mutect2, varscan2
- IGKV1D-16 | c.195C>A p.A65= | Silent (SNP) | VAF 110/339 reads (32%) | catalogued as rs1248798525; called by muse, mutect2, varscan2
- LRATD2 | c.429G>A p.V143= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs1200111683, COSV100513667; called by muse, mutect2, varscan2
- LRP5 | c.1407G>A p.V469= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1404758320, COSV99592617; called by muse, mutect2, varscan2
- LUM | c.558C>G p.L186= | Silent (SNP) | VAF 41/53 reads (77%) | catalogued as rs144214151, COSV99899194; called by muse, mutect2, varscan2
- MAGI3 | c.3120G>A p.E1040= | Silent (SNP) | VAF 69/110 reads (63%) | catalogued as rs754189647, COSV56846337; called by muse, mutect2, varscan2
- MAMDC4 | c.3501G>A p.V1167= (on ENST00000445819; = p.V1088= on NM_206920.3) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99808270; called by muse, mutect2, varscan2
- MAST4 | c.2223A>G p.K741= (on ENST00000403625 / NM_001164664.2; = p.K552= on NM_015183.3) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99845875; called by muse, mutect2, varscan2
- MSC | c.615C>A p.T205= | Silent (SNP) | VAF 226/581 reads (39%) | catalogued as COSV100335913; called by muse, mutect2, varscan2
- MUC3A | c.7956C>G p.L2652= | Silent (SNP) | VAF 133/806 reads (17%) | catalogued as COSV100114011, COSV100115086; called by muse, mutect2
- MYO18B | c.3489C>A p.T1163= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100125185; called by muse, mutect2, varscan2
- NAPRT | c.1032G>T p.V344= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99435594; called by muse, mutect2, varscan2
- OR1N2 | c.21G>C p.V7= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV101031469; called by muse, mutect2, varscan2
- OR5P2 | c.456T>C p.A152= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100271444; called by muse, mutect2, varscan2
- PANK3 | c.9C>T p.I3= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99496593; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1170C>T p.F390= | Silent (SNP) | VAF 77/239 reads (32%) | catalogued as COSV99461841; called by muse, mutect2, varscan2
- RABEP2 | c.1269C>T p.C423= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100707217; called by muse, mutect2, varscan2
- SAFB2 | c.1710G>C p.R570= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99386108; called by muse, mutect2, varscan2
- SCN3A | c.2862C>A p.V954= | Silent (SNP) | VAF 202/362 reads (56%) | catalogued as COSV51828253, COSV99329279; called by muse, mutect2, varscan2
- SINHCAF | c.513G>A p.K171= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100530730; called by muse, mutect2, varscan2
- SLC15A1 | c.756T>C p.S252= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100919538; called by muse, mutect2, varscan2
- SLC24A5 | c.1392C>T p.D464= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as COSV99982153; called by muse, mutect2, varscan2
- STIL | c.3282C>T p.S1094= | Silent (SNP) | VAF 72/117 reads (62%) | catalogued as COSV99681348; called by muse, mutect2, varscan2
- STK31 | c.2562A>G p.S854= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV100669949; called by muse, mutect2, varscan2
- STK31 | c.2916C>T p.F972= | Silent (SNP) | VAF 70/131 reads (53%) | catalogued as COSV63456209, COSV63457937; called by muse, mutect2, varscan2
- TECRL | c.867C>T p.N289= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs1438692591, COSV101169384; called by muse, mutect2, varscan2
- TRGV2 | c.354G>T p.G118= | Silent (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- VKORC1 | c.147C>T p.I49= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100161855; called by muse, mutect2, varscan2
- ZIM3 | c.1398G>A p.Q466= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as COSV99518664; called by muse, mutect2, varscan2
- ZNF233 | c.1845G>T p.T615= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV100492465, COSV61934325; called by muse, mutect2, varscan2
- ZNF776 | c.690C>A p.L230= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100414345; called by muse, mutect2, varscan2
- EPDR1 | c.-261G>T | 5'UTR (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99554685; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899639 C>A | 3'Flank (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- MRPL39 | c.969+1114C>T | Intron (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100221108; called by muse, mutect2, varscan2
- PLEC | c.524-3793C>A | Intron (SNP) | VAF 24/39 reads (62%) | catalogued as COSV100519050; called by muse, varscan2
- RIMS2 | c.4064-21234G>T | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99199826; called by muse, mutect2, varscan2
- TRAF2 | c.*217G>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as rs746360575, COSV99916837; called by muse, mutect2, varscan2
- UBTFL2 | n.665G>T | RNA (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
